Somatic mutation profile of tumor specimen C3L-00360-01 (aliquot CPT0002350008) from CPTAC case C3L-00360, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G3; Age at diagnosis: 72.3 years (26,395 days).
Specimen C3L-00360-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1c77cb2e-0c2c-4ddc-8b87-adb78ede58ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-00360-71 (Blood Derived Normal), aliquot CPT0004380002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b785fbf1-a723-4beb-b361-a391eec51907

The open-access MAF lists 93 somatic variants for this specimen: 59 protein-altering or splice-affecting, 18 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 43, Silent 18, Frame Shift Del 7, Intron 6, 3'UTR 4, Nonsense Mutation 4, 5'UTR 3, Splice Site 2, In Frame Del 2, 5'Flank 2, Frame Shift Ins 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD33 | c.263-1G>A p.X88_splice (on ENST00000340970 / NM_001304459.2; = p.X213_splice on NM_182608.4) | Splice Site (SNP) | VAF 13/95 reads (14%) | catalogued as rs760357970; called by muse, mutect2, varscan2
- CHST6 | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 171/903 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.285); catalogued as rs1299395607; called by muse, mutect2, varscan2
- DIAPH2 | c.1607G>T p.R536L | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.647); catalogued as COSV61277524; called by muse, mutect2, varscan2
- FAT2 | c.6377C>A p.S2126* | Nonsense Mutation (SNP) | VAF 90/226 reads (40%) | catalogued as COSV99941451; called by muse, mutect2, varscan2
- FTL | c.466G>A p.G156S | Missense Mutation (SNP) | VAF 56/290 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs151265703; called by muse, mutect2, varscan2
- GPR108 | c.1249G>A p.V417I (on ENST00000264080 / NM_001080452.1; = p.V175I on NM_020171.2) | Missense Mutation (SNP) | VAF 46/227 reads (20%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.895); catalogued as rs542165016; called by muse, mutect2, varscan2
- LRIG2 | c.1867T>C p.C623R | Missense Mutation (SNP) | VAF 39/185 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1433894143; called by muse, mutect2, varscan2
- PIGQ | c.794A>G p.K265R | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as rs375666595; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKAR1A | c.1037A>G p.K346R | Missense Mutation (SNP) | VAF 30/370 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.569); catalogued as rs1466357740, COSV56835426; called by muse, mutect2
- SPEF1 | c.388C>G p.P130A | Missense Mutation (SNP) | VAF 36/196 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.122); catalogued as COSV65727998; called by muse, mutect2, varscan2
- USH2A | c.14948T>C p.I4983T | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs765747576; called by muse, mutect2
- ZNF200 | c.638G>T p.R213M | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV101205262; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.3467A>G p.Y1156C | Missense Mutation (SNP) | VAF 130/302 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ANXA11 | c.1126G>C p.E376Q | Missense Mutation (SNP) | VAF 26/155 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ARRDC4 | c.542A>C p.Q181P | Missense Mutation (SNP) | VAF 16/131 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- ASPN | c.1128_1136del p.N377_G379del | In Frame Del (DEL) | VAF 21/142 reads (15%) | called by mutect2, pindel, varscan2
- AXIN2 | c.1647T>A p.Y549* | Nonsense Mutation (SNP) | VAF 45/226 reads (20%) | called by muse, mutect2, varscan2
- CAPN9 | c.1463A>C p.E488A | Missense Mutation (SNP) | VAF 104/324 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- CARMIL2 | c.3507_3519del p.R1170Pfs*4 | Frame Shift Del (DEL) | VAF 12/51 reads (24%) | called by mutect2, pindel, varscan2
- CCDC146 | c.2568A>T p.E856D | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- CCDC168 | c.9687del p.A3230Hfs*5 | Frame Shift Del (DEL) | VAF 12/75 reads (16%) | called by mutect2, pindel, varscan2
- CETP | c.916G>A p.G306R | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- COL18A1 | c.3460G>A p.G1154R (on ENST00000359759 / NM_130444.3; = p.G919R on NM_030582.4) | Missense Mutation (SNP) | VAF 60/303 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH6 | c.997T>A p.Y333N | Missense Mutation (SNP) | VAF 36/192 reads (19%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- DSC3 | c.2639del p.N880Ifs*10 | Frame Shift Del (DEL) | VAF 60/299 reads (20%) | called by mutect2, pindel, varscan2
- ELF3 | c.76C>A p.L26M | Missense Mutation (SNP) | VAF 12/178 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.201); called by muse, mutect2
- EMG1 | c.433A>G p.S145G | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.037); called by muse, mutect2
- ESPN | c.1955A>G p.N652S | Missense Mutation (SNP) | VAF 39/472 reads (8%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.996); called by muse, mutect2
- FBXO10 | c.155G>A p.C52Y | Missense Mutation (SNP) | VAF 41/249 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- GPC3 | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 79/188 reads (42%) | SIFT tolerated (0.13); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GPI | c.641C>G p.T214S | Missense Mutation (SNP) | VAF 67/373 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- IRF2BP2 | c.460A>G p.N154D | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.001); called by muse, mutect2
- KCNK5 | c.1146A>C p.E382D | Missense Mutation (SNP) | VAF 38/171 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- LIPH | c.1206A>G p.I402M | Missense Mutation (SNP) | VAF 66/362 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- MARCHF2 | c.555del p.F186Sfs*31 | Frame Shift Del (DEL) | VAF 38/229 reads (17%) | called by mutect2, pindel, varscan2
- MATN1 | c.359C>T p.T120I | Missense Mutation (SNP) | VAF 18/239 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- MLYCD | c.922A>C p.I308L | Missense Mutation (SNP) | VAF 73/420 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); called by muse, mutect2, varscan2
- MON2 | c.3646G>A p.G1216R | Missense Mutation (SNP) | VAF 34/224 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.495); called by mutect2, varscan2
- MTUS2 | c.1131C>A p.N377K | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- NR2C1 | c.189T>A p.D63E | Missense Mutation (SNP) | VAF 74/478 reads (15%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCK1 | c.211_213del p.K71del | In Frame Del (DEL) | VAF 28/151 reads (19%) | called by pindel, varscan2
- PIK3R1 | c.1414_1415insA p.R472Qfs*14 (on ENST00000521381 / NM_181523.3; = p.R202Qfs*14 on NM_181504.4) | Frame Shift Ins (INS) | VAF 6/45 reads (13%) | called by mutect2, varscan2
- PUM1 | c.1526G>C p.S509T | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.003); called by muse, mutect2
- RBM6 | c.2683-1G>T p.X895_splice | Splice Site (SNP) | VAF 14/62 reads (23%) | called by muse, varscan2
- RBPMS2 | c.611A>T p.K204M | Missense Mutation (SNP) | VAF 21/163 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RGN | c.18T>G p.I6M | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.538); called by muse, varscan2
- SAP30BP | c.668T>G p.F223C | Missense Mutation (SNP) | VAF 21/178 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SCAPER | c.3176T>A p.V1059E | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- SH2B1 | c.1872T>A p.Y624* | Nonsense Mutation (SNP) | VAF 63/379 reads (17%) | called by muse, mutect2, varscan2
- SLC12A7 | c.556T>C p.Y186H | Missense Mutation (SNP) | VAF 31/165 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SNX5 | c.584A>G p.D195G | Missense Mutation (SNP) | VAF 26/109 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- SUPT16H | c.577G>A p.V193I | Missense Mutation (SNP) | VAF 34/156 reads (22%) | SIFT tolerated (0.51); PolyPhen benign (0.164); called by muse, mutect2, varscan2
- TBR1 | c.648A>T p.K216N | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- TMEM11 | c.11G>A p.W4* | Nonsense Mutation (SNP) | VAF 50/316 reads (16%) | called by muse, mutect2, varscan2
- TNFRSF13B | c.101G>A p.C34Y | Missense Mutation (SNP) | VAF 96/476 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TRPM4 | c.3605del p.G1202Vfs*31 | Frame Shift Del (DEL) | VAF 69/364 reads (19%) | called by mutect2, pindel, varscan2
- TSN | c.5C>A p.S2Y | Missense Mutation (SNP) | VAF 42/225 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- VHL | c.544_548del p.R182Afs*72 | Frame Shift Del (DEL) | VAF 75/406 reads (18%) | called by mutect2, pindel, varscan2
- WHAMM | c.1327del p.V443Sfs*16 | Frame Shift Del (DEL) | VAF 11/77 reads (14%) | called by mutect2, pindel, varscan2
- AGAP1 | c.510G>A p.E170= | Silent (SNP) | VAF 27/143 reads (19%) | catalogued as COSV100363508; called by muse, mutect2, varscan2
- APOC2 | c.220T>C p.L74= | Silent (SNP) | VAF 65/359 reads (18%) | called by muse, mutect2, varscan2
- ARR3 | c.252A>G p.P84= | Silent (SNP) | VAF 40/141 reads (28%) | called by muse, mutect2, varscan2
- C4A | c.2731C>T p.L911= | Silent (SNP) | VAF 151/984 reads (15%) | called by muse, mutect2, varscan2
- DNAJC10 | c.505A>C p.R169= | Silent (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- DPEP1 | c.93T>C p.P31= | Silent (SNP) | VAF 17/117 reads (15%) | called by muse, mutect2, varscan2
- ECHS1 | c.261C>T p.L87= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs770887037; called by muse, mutect2, varscan2
- KIAA1755 | c.51C>A p.L17= | Silent (SNP) | VAF 65/392 reads (17%) | catalogued as COSV99642709; called by muse, mutect2, varscan2
- LILRB1 | c.30C>T p.G10= | Silent (SNP) | VAF 22/128 reads (17%) | called by muse, varscan2
- MUC20 | c.1326A>G p.T442= | Silent (SNP) | VAF 38/242 reads (16%) | called by mutect2, varscan2
- NEDD4 | c.1878C>G p.T626= (on ENST00000508342 / NM_001284338.1; = p.T207= on NM_006154.4) | Silent (SNP) | VAF 15/187 reads (8%) | catalogued as rs1305103721; called by muse, mutect2
- PPP1R27 | c.396G>T p.L132= | Silent (SNP) | VAF 40/228 reads (18%) | called by muse, mutect2, varscan2
- RBMXL3 | c.2319C>T p.Y773= | Silent (SNP) | VAF 58/168 reads (35%) | catalogued as rs782044389; called by muse, mutect2, varscan2
- RGS3 | c.3432G>A p.T1144= (on ENST00000350696 / NM_001282923.2; = p.T863= on NM_130795.4) | Silent (SNP) | VAF 16/95 reads (17%) | catalogued as rs758491530, COSV59514509; called by muse, mutect2, varscan2
- UNC80 | c.6654G>A p.A2218= | Silent (SNP) | VAF 20/156 reads (13%) | catalogued as rs370522501, COSV55887118; called by muse, mutect2, varscan2
- WDR18 | c.555C>A p.P185= | Silent (SNP) | VAF 27/117 reads (23%) | called by muse, mutect2, varscan2
- XKR7 | c.351G>A p.S117= | Silent (SNP) | VAF 25/151 reads (17%) | catalogued as rs1434415866; called by muse, mutect2, varscan2
- ZNF773 | c.786C>T p.L262= | Silent (SNP) | VAF 27/208 reads (13%) | catalogued as rs1367850931, COSV56588210, COSV99989287; called by muse, mutect2, varscan2
- ABHD3 | c.668+427T>C | Intron (SNP) | VAF 24/154 reads (16%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500090 T>C | 5'Flank (SNP) | VAF 9/52 reads (17%) | called by muse, mutect2, varscan2
- C16orf91 | c.*97C>A | 3'UTR (SNP) | VAF 58/324 reads (18%) | called by muse, mutect2, varscan2
- CCDC25 | c.*13A>T | 3'UTR (SNP) | VAF 9/56 reads (16%) | called by muse, mutect2, varscan2
- CD8A | c.*532T>A | 3'UTR (SNP) | VAF 59/276 reads (21%) | catalogued as rs1184725928; called by muse, mutect2, varscan2
- CLCN2 | c.-1G>A | 5'UTR (SNP) | VAF 54/345 reads (16%) | called by muse, mutect2, varscan2
- COMMD4P1 | chr15:77941507 del A | 3'Flank (DEL) | VAF 52/163 reads (32%) | called by mutect2, pindel, varscan2
- MACF1 | c.15832-10360A>T | Intron (SNP) | VAF 16/151 reads (11%) | called by muse, mutect2, varscan2
- MRPL28 | c.288+335_288+339del | Intron (DEL) | VAF 16/121 reads (13%) | called by mutect2, pindel, varscan2
- NELL1 | c.-18C>T | 5'UTR (SNP) | VAF 24/148 reads (16%) | catalogued as rs761619973, COSV100123141; called by muse, mutect2, varscan2
- NOP53 | c.-13T>A | 5'UTR (SNP) | VAF 36/282 reads (13%) | catalogued as COSV54408344; called by muse, mutect2
- PCK1 | c.1187-22C>T | Intron (SNP) | VAF 57/314 reads (18%) | catalogued as rs201340867; called by muse, mutect2, varscan2
- RNPS1 | c.-181+19C>A | Intron (SNP) | VAF 32/239 reads (13%) | called by muse, mutect2, varscan2
- SAMD8 | chr10:75111638 C>A | 5'Flank (SNP) | VAF 5/15 reads (33%) | called by muse, mutect2, varscan2
- SLC7A13 | c.1180-966C>A | Intron (SNP) | VAF 18/66 reads (27%) | called by muse, varscan2
- ZNF384 | c.*60A>G | 3'UTR (SNP) | VAF 22/244 reads (9%) | called by muse, mutect2
